Somatic mutation profile of tumor specimen MP2PRT-PAPRWD-TMP1-A (aliquot MP2PRT-PAPRWD-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPRWD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (727 days).
Specimen MP2PRT-PAPRWD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 684837d0-4296-4cda-a2e8-dd2fd1e8d94d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPRWD-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPRWD-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/caf42561-b872-466c-a075-87829d0f534a

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GAT1 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 23/644 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1451695136, COSV56998935; called by muse, mutect2
- LYPD3 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 172/389 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs781304337, COSV54989593; called by muse, mutect2, varscan2
- SON | c.5867G>A p.R1956H | Missense Mutation (SNP) | VAF 324/661 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs1186464714, COSV51659106, COSV99276580; called by muse, mutect2, varscan2
- HSPA4L | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 94/193 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAGI1 | c.825C>G p.I275M | Missense Mutation (SNP) | VAF 27/447 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.29); called by muse, mutect2
- NR6A1 | c.449A>T p.E150V (on ENST00000487099 / NM_033334.4; = p.E146V on NM_001489.5) | Missense Mutation (SNP) | VAF 111/228 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- OR4D10 | c.504C>T p.F168= | Silent (SNP) | VAF 11/372 reads (3%) | called by muse, mutect2
